MMRF case MMRF_2147 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/b539f267-ccf2-4308-844d-1dc0e43f6d2f

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 65 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 65.3 years (23,853 days); ISS stage: II; Days to last known disease status: 617 days (1.7 years); Days to last follow up: 617 days (1.7 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 2 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 22 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 21 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 12 days; Days to treatment end: 16 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 29 days; Days to treatment end: 274 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 29 days; Days to treatment end: 281 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 29 days; Days to treatment end: 280 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 309 days; Days to treatment end: 392 days (1.1 years).

Follow-up (1 entry)
- Follow-up contact recording only the day: day 617.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -62 (ECOG 0): M Protein 4.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 201 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.159 mg/dL; Immunoglobulin G 59.4 g/L; Immunoglobulin A 0.08 g/L; Immunoglobulin M 0.07 g/L; Beta 2 Microglobulin 3.99 µg/mL; Lactate Dehydrogenase 2.45 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.42 ×10⁹/L; Platelets 167 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.18 mmol/L; Calcium 2.4 mmol/L; Albumin 38 g/L; Total Protein 11.3 g/dL; C-Reactive Protein 0.3 mg/dL.
- Day 29 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 8.99 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.635 mg/dL; Immunoglobulin G 18.9 g/L; Immunoglobulin A 0.11 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.86 ×10⁹/L; Platelets 235 ×10⁹/L; Creatinine 88.4 µmol/L; Calcium 2.25 mmol/L.
- Day 115 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 5.34 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.9 mg/dL; Immunoglobulin G 6.44 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 4.17 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 4.4 ×10⁹/L; Absolute Neutrophil 2.74 ×10⁹/L; Platelets 122 ×10⁹/L; Creatinine 88.4 µmol/L; Calcium 2.3 mmol/L; Glucose 5.23 mmol/L.
- Day 204 (ECOG 0): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.01 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.575 mg/dL; Immunoglobulin G 6.56 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.09 g/L; Lactate Dehydrogenase 2.42 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.86 ×10⁹/L; Platelets 101 ×10⁹/L; Creatinine 115 µmol/L; Calcium 2.33 mmol/L; Glucose 5.06 mmol/L.
- Day 308 (ECOG 0): Lactate Dehydrogenase 3.6 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 4.93 ×10⁹/L; Platelets 159 ×10⁹/L; Creatinine 106 µmol/L; Blood Urea Nitrogen 7.25 mmol/L; Calcium 2.6 mmol/L; Albumin 45 g/L; Total Protein 6.5 g/dL; Glucose 5.94 mmol/L.
- Day 392 (ECOG 0): M Protein 0.7 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 13.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.93 mg/dL; Immunoglobulin G 12.3 g/L; Immunoglobulin A 0.45 g/L; Immunoglobulin M 0.19 g/L; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 9.05 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 5.03 ×10⁹/L; Platelets 228 ×10⁹/L; Creatinine 106 µmol/L; Calcium 2.55 mmol/L; Glucose 5.12 mmol/L.
- Day 483 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 22.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.639 mg/dL; Immunoglobulin G 13.6 g/L; Immunoglobulin A 0.37 g/L; Immunoglobulin M 0.14 g/L; Hemoglobin 8.8 mmol/L; Leukocytes 6 ×10⁹/L; Absolute Neutrophil 4.54 ×10⁹/L; Platelets 211 ×10⁹/L; Creatinine 97.2 µmol/L; Glucose 4.57 mmol/L.
- Day 554 (ECOG 0): M Protein 1.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 34.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.588 mg/dL; Immunoglobulin G 14.6 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.12 g/L; Lactate Dehydrogenase 2.95 µkat/L; Hemoglobin 8.06 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 4.26 ×10⁹/L; Platelets 162 ×10⁹/L; Creatinine 115 µmol/L; Blood Urea Nitrogen 4.96 mmol/L; Calcium 2.25 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 4.84 mmol/L.

Other clinical attributes
- Day -62: Weight: 101 kg; Height: 178 cm.

Family history
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2147_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -62 days.
- Sample MMRF_2147_2_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -62 days.
